Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4622, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4622-01A (Primary Tumor).

Diagnosis:

kidney, left, laparoscopic nephrectomy

Histologic tumor type/subtype: Two separate renal tumors are present in this kidney, both are renal cell carcinoma, clear cell type.

Histologic grade (if applicable): Both tumors are nuclear grade III (of IV)

Tumor size (greatest dimension): 4.8 cm and 3.2 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: The lower pole kidney tumor involves the renal sinus

Gerota's fascia: Both tumors do not invade into Gerota's fascia

Renal vein: Free of tumor

Ureter: Free of tumor

Venous (large vessel) Not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: Free of tumor

Gerota's fascia: Free of tumor

Renal vein: Free of tumor

Renal artery: Free of tumor

Ureter: Free of tumor

Adrenal gland: Not present in this specimen

Lymph nodes: None submitted

Other significant findings: There are a few totally and partially sclerotic glomeruli, patchy interstitial chronic inflammation and fibrosis, arteriolonephrosclerosis.

AJCC Staging:

T3a

Ix

pM1

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

clinical diagnosis of kidney cancer.

Gross Description:

Specimen fixation: formalin

Type of specimen: laparoscopic nephrectomy

Side of specimen: left

Size and weight of specimen: 1080 grams, 25 x 16 x 11 cm nephrectomy specimen
(kidney is 12 x 8 x 7 cm)

Orientation: There is no orientation provided. At the time of Tissue Procurement triage, the entire specimen is inked blue.

Presence/absence of adrenal gland: There is no adrenal gland identified.

Tumor description/site: There are two separate tumors in this kidney. The first tumor is in the posterior upper pole, in the lateral anterior aspect and the second tumor is in the posterior mid to lower pole of the kidney. Both of these masses are cortical and well-circumscribed. Both have a golden yellow cut surface with small pinpoint areas of hemorrhage. There are no gross areas of necrosis or calcification. The upper pole lesion has a central cystic area, which is filled with hemorrhagic material.

Tumor size: The upper pole lesion is 3.2 x 2.7 x 1.9 cm, the mid to lower pole lesion is 4.8 x 4.5 x 3.7 cm.

Presence/absence of multicentricity: present; There are two separate mass lesions identified. These mass lesions are 1.8 cm from one another.

Source: NCI Genomic Data Commons file 434923e2-8959-4561-b35f-4ff8fcd4c31e (TCGA-B8-4622.ABB9B759-D869-41CD-B2D9-48E3082F1FF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).